Surgical pathology report (de-identified scan), TCGA case TCGA-AP-A052, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma), tissue source site MSKCC, specimen TCGA-AP-A052-01A (Primary Tumor).

Specimens Submitted:

- 1: SP: Omentum (fs)
- 2: SP: Uterus, bilateral tubes and ovaries
- 3: SP: Bladder tumor

ICD-0-3

adenocarcinoma, serous, NOS 8441/3

Site: Endometrium C54.1

hw
5/2/11

DIAGNOSIS:

- 1) OMENTUM; EXCISION:
- METASTATIC PAPILLARY SEROUS CARCINOMA, HIGH GRADE, INVOLVING OMENTUM, .
- PSAMMOMATOUS CALCIFICATIONS ARE PRESENT.
- 2) UTERUS, BILATERAL FALLOPIAN TUBES AND OVARIES; HYSTERECTOMY AND BILATERAL SALPINGO-OOPHORECTOMY:
- ADENOCARCINOMA OF ENDOMETRIUM, PAPILLARY SEROUS TYPE, HIGH GRADE.
- THE TUMOR IS LIMITED TO THE ENDOMETRIUM AND INVOLVES ENDOMETRIAL POLYPS.
- THE MYOMETRIUM SHOWS THE FOLLOWING ABNORMALITY: LEIOMYOMATA.
- THE RIGHT AND LEFT OVARIES ARE INVOLVED BY PAPILLARY SEROUS CARCINOMA ON THEIR SURFACES.
- THE LEFT FALLOPIAN TUBE IS INVOLVED BY PAPILLARY SEROUS CARCINOMA.
- LYMPHOVASCULAR TUMOR EMBOLI ARE NOTED IN THE LEFT OVARY.
- THE TUMOR ALSO INVOLVES THE SEROSAL SURFACE OF THE UTERUS.

NOTE: THE SLIDES FROM PREVIOUS ACCESSION [REDACTED] WERE REVIEWED, AND THE MORPHOLOGIC FEATURES OF THE TUMOR WERE FOUND TO BE SIMILAR TO THOSE OF THE CURRENT SPECIMEN.

- 3) BLADDER TUMOR; BIOPSY:
- METASTATIC PAPILLARY SEROUS CARCINOMA INVOLVING BLADDER SEROSA AND FIBROADIPOSE TISSUE.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

** Continued on next page **

HIFAA Discrepancy		☒

hw 5/2/11

Source: NCI Genomic Data Commons file 9e66f8a9-e2c2-4531-9baf-a357d2a446ad (TCGA-AP-A052.830EF496-4672-4E9A-B662-DCB4678E99B0.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).